Somatic mutation profile of tumor specimen TARGET-10-PANUXS-09A (aliquot TARGET-10-PANUXS-09A-01D) from TARGET case TARGET-10-PANUXS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (789 days).
Specimen TARGET-10-PANUXS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 410c0559-54fb-44fd-883d-0f631cd9e76f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANUXS-14A (Bone Marrow Normal), aliquot TARGET-10-PANUXS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ca5a36-411b-47da-b42b-b783cac66e87

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Del 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs776347334, COSV61460793; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGAP3 | c.1135G>A p.G379S (on ENST00000622464; = p.G415S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs535196546; called by muse, mutect2, varscan2
- SERPINA9 | c.315_316dup p.P106Hfs*17 | Frame Shift Ins (INS) | VAF 15/83 reads (18%) | catalogued as rs1453770363; called by mutect2, varscan2
- SPATA17 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375338290; called by muse, mutect2, varscan2
- SPHKAP | c.3912G>T p.M1304I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100764209; called by muse, mutect2
- ST6GALNAC6 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | PolyPhen possibly damaging (0.855); catalogued as COSV52537004; called by mutect2, varscan2
- GPATCH1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, varscan2
- IL32 | c.610C>A p.L204I (on ENST00000396890 / NM_001308078.4; = p.L158I on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2
- MAST4 | c.4079G>A p.G1360E (on ENST00000403625 / NM_001164664.2; = p.G1171E on NM_015183.3) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.3743G>T p.R1248M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- PWWP3B | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- SCN7A | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); called by muse, mutect2
- SRSF10 | c.90del p.F30Lfs*7 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.3969G>A p.K1323= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs145628622; called by muse, mutect2, varscan2
